Somatic mutation profile of tumor specimen 0DWI1A from CCDI case PBCMGS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 5.7 years (2,067 days).
Specimen 0DWI1A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 779b6334-cf18-4aa1-b5cb-4675126d8a6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWHZ4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43e94739-21e6-472e-976f-5ad76b5766eb

The open-access MAF lists 30 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 4, Intron 2, Nonsense Mutation 2, Frame Shift Ins 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXO38 | c.1109C>G p.A370G | Missense Mutation (SNP) | VAF 141/414 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs779899138; called by muse, mutect2, varscan2
- GRAP2 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 268/715 reads (37%) | catalogued as rs772467549; called by muse, mutect2, varscan2
- MROH2A | c.4441G>A p.D1481N | Missense Mutation (SNP) | VAF 212/654 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.318); catalogued as rs1268782439; called by muse, mutect2, varscan2
- OR4B1 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 266/710 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772827334; called by muse, mutect2, varscan2
- POTEC | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 87/211 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.187); catalogued as COSV62803472; called by muse, mutect2, varscan2
- SLC15A1 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 321/914 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs201099957; called by muse, mutect2, varscan2
- TENM3 | c.8057A>G p.N2686S | Missense Mutation (SNP) | VAF 145/250 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.042); catalogued as rs1305513314; called by muse, mutect2, varscan2
- WWC2 | c.3055C>T p.R1019W | Missense Mutation (SNP) | VAF 180/274 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67857663; called by muse, mutect2, varscan2
- ZBED3 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs1356991879; called by muse, varscan2
- ZNF251 | c.790C>A p.P264T | Missense Mutation (SNP) | VAF 166/404 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs1346618959; called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 35/1044 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- HYDIN | c.10375G>T p.A3459S | Missense Mutation (SNP) | VAF 147/408 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LCE1E | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 74/1051 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MDN1 | c.8717dup p.H2907Afs*2 | Frame Shift Ins (INS) | VAF 344/1025 reads (34%) | called by mutect2, varscan2
- MROH2A | c.4442A>T p.D1481V | Missense Mutation (SNP) | VAF 211/641 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OXER1 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 191/624 reads (31%) | called by muse, mutect2, varscan2
- RYR1 | c.6230A>T p.E2077V | Missense Mutation (SNP) | VAF 137/655 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SLC15A2 | c.1630G>T p.G544C | Missense Mutation (SNP) | VAF 338/861 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SPHKAP | c.5011A>G p.I1671V (on ENST00000392056 / NM_001142644.2; = p.I1642V on NM_030623.3) | Missense Mutation (SNP) | VAF 36/910 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2
- TOMM40L | c.674C>A p.A225E | Missense Mutation (SNP) | VAF 134/342 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- UGT2A2 | c.121C>A p.H41N | Missense Mutation (SNP) | VAF 226/364 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- ZNF445 | c.1687C>G p.H563D | Missense Mutation (SNP) | VAF 27/474 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ABCA9 | c.891G>T p.L297= | Silent (SNP) | VAF 379/1486 reads (26%) | called by muse, mutect2, varscan2
- ADAMTS3 | c.1791C>T p.Y597= | Silent (SNP) | VAF 226/416 reads (54%) | called by muse, mutect2, varscan2
- EPX | c.885G>A p.K295= | Silent (SNP) | VAF 394/1422 reads (28%) | called by muse, mutect2, varscan2
- THAP4 | c.1149C>T p.S383= | Silent (SNP) | VAF 27/376 reads (7%) | catalogued as rs776791686, COSV67191197; called by muse, mutect2
- AXDND1 | c.2799-80C>A | Intron (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- CINP | chr14:102362899 C>T | 5'Flank (SNP) | VAF 104/288 reads (36%) | called by muse, mutect2, varscan2
- SAG | c.648+16C>T | Intron (SNP) | VAF 106/284 reads (37%) | catalogued as rs759189697; called by muse, mutect2, varscan2
- WARS1 | c.-249C>G | 5'UTR (SNP) | VAF 54/158 reads (34%) | called by muse, mutect2, varscan2
